Somatic mutation profile of tumor specimen 803736b3-9ca9-4f9f-bdfe-8783e3 (aliquot 803736b3-9ca9-4f9f-bdfe-8783e3_D6) from CPTAC case 05CO020, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen 803736b3-9ca9-4f9f-bdfe-8783e3: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba118a89-8839-4a58-a605-afe3be6a7be7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0a573420-cece-4cb1-ba68-00ede0 (Blood Derived Normal), aliquot 0a573420-cece-4cb1-ba68-00ede0_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/763a80e0-7200-4058-aca6-65dd52d30de7

The open-access MAF lists 291 somatic variants for this specimen: 176 protein-altering or splice-affecting, 70 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 156, Silent 70, Intron 24, Nonsense Mutation 8, RNA 7, 3'UTR 7, Frame Shift Ins 4, Splice Site 3, 5'UTR 3, 3'Flank 2, Frame Shift Del 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 92/357 reads (26%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 122/490 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.4682G>A p.R1561Q | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1328373039, CM157243, COSV54034274; called by muse, mutect2, varscan2
- ABCB4 | c.652C>T p.L218F | Missense Mutation (SNP) | VAF 134/495 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55943015; called by muse, mutect2, varscan2
- ABHD17A | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 24/259 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1414922914; called by muse, mutect2
- ACBD7 | c.260G>C p.G87A | Missense Mutation (SNP) | VAF 99/262 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV62252816; called by muse, mutect2, varscan2
- ADGRF4 | c.1843G>C p.G615R | Missense Mutation (SNP) | VAF 91/295 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99347982; called by muse, mutect2, varscan2
- ANK1 | c.4384G>A p.A1462T | Missense Mutation (SNP) | VAF 193/639 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs368572433; called by muse, mutect2, varscan2
- AQP3 | c.200T>C p.V67A | Missense Mutation (SNP) | VAF 106/379 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as rs752146716; called by muse, mutect2, varscan2
- ARHGEF26 | c.2297C>T p.T766M | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs768573483, COSV100726739; called by muse, mutect2, varscan2
- ARL4D | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 125/447 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs768448857; called by muse, mutect2, varscan2
- ATP1A3 | c.257C>T p.P86L (on ENST00000545399 / NM_001256214.2; = p.P73L on NM_152296.5) | Missense Mutation (SNP) | VAF 268/468 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1161880070, COSV57485078; called by muse, mutect2, varscan2
- ATP2B2 | c.1265C>T p.T422M (on ENST00000352432; = p.T388M on NM_001683.5) | Missense Mutation (SNP) | VAF 194/703 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770734675, COSV59500521; called by muse, mutect2, varscan2
- CACNA2D4 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs375121955, COSV54944517; called by muse, mutect2, varscan2
- CAPN13 | c.1276T>A p.F426I | Missense Mutation (SNP) | VAF 132/419 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.526); catalogued as rs377694077, COSV99700627; called by mutect2, varscan2
- CCDC171 | c.2897C>T p.T966M | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141258483; called by mutect2, varscan2
- CCDC180 | c.4697G>A p.R1566H | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs186799713; called by muse, mutect2, varscan2
- CCDC80 | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 124/558 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.283); catalogued as rs1368063182; called by mutect2, varscan2
- CD33 | c.231G>C p.K77N | Missense Mutation (SNP) | VAF 51/285 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1489088133; called by muse, mutect2, varscan2
- CLDN17 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 107/355 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.024); catalogued as rs770504734, COSV54522295; called by muse, mutect2, varscan2
- CROCC | c.5701G>A p.A1901T | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as rs768679535; called by muse, mutect2, varscan2
- CSMD3 | c.1593A>C p.E531D (on ENST00000297405 / NM_001363185.1; = p.E427D on NM_052900.3) | Missense Mutation (SNP) | VAF 90/404 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as COSV52105113, COSV52338075; called by muse, mutect2, varscan2
- CTR9 | c.1846C>T p.H616Y | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100797547; called by muse, mutect2, varscan2
- CYP51A1 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.853); catalogued as rs757428909, COSV50153851; called by muse, mutect2, varscan2
- DCLK2 | c.1249G>A p.G417R | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.16); catalogued as COSV56201428; called by muse, mutect2, varscan2
- DNAH3 | c.8971C>T p.R2991C | Missense Mutation (SNP) | VAF 26/445 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as rs777070451, COSV54544657; called by muse, mutect2
- DST | c.11980G>A p.A3994T (on ENST00000361203 / NM_001374722.1; = p.A1582T on NM_015548.5) | Missense Mutation (SNP) | VAF 68/255 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV55032097; called by muse, mutect2, varscan2
- FBLN2 | c.2200G>A p.E734K | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1012806680; called by muse, mutect2, varscan2
- FOLH1 | c.1848G>A p.M616I | Missense Mutation (SNP) | VAF 137/436 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV57045256; called by muse, mutect2, varscan2
- GPR45 | c.190G>T p.A64S | Missense Mutation (SNP) | VAF 116/408 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.688); catalogued as COSV51525046, COSV99306565; called by mutect2, varscan2
- GRID2 | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 67/255 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs772260836, COSV56271597; called by muse, mutect2, varscan2
- GRM5 | c.2459C>T p.P820L | Missense Mutation (SNP) | VAF 133/402 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747778918, COSV100555017; called by muse, mutect2, varscan2
- HECTD4 | c.12746G>A p.R4249Q | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs545772641; called by muse, mutect2, varscan2
- HNRNPU | c.926A>C p.N309T (on ENST00000283179; = p.N371T on NM_004501.3) | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as rs200174361; called by muse, mutect2, varscan2
- IFNA10 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 67/284 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV99497433; called by muse, mutect2, varscan2
- IL21R | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.063); catalogued as rs367586016; called by muse, mutect2, varscan2
- IQSEC3 | c.2581A>T p.T861S (on ENST00000538872 / NM_001170738.2; = p.T558S on NM_015232.1) | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as rs782662417; called by mutect2, varscan2
- IWS1 | c.892C>T p.R298* | Nonsense Mutation (SNP) | VAF 69/178 reads (39%) | catalogued as rs763687905; called by muse, mutect2, varscan2
- KIF4B | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 110/447 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775915028, COSV70528329; called by muse, mutect2, varscan2
- KSR2 | c.2381A>G p.Y794C | Missense Mutation (SNP) | VAF 49/271 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs78294559; called by muse, mutect2, varscan2
- LEO1 | c.1664G>A p.R555Q | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); catalogued as COSV55176163; called by muse, mutect2, varscan2
- LRFN5 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.151); catalogued as rs553209511, COSV53242167, COSV53256587; called by muse, mutect2, varscan2
- MACO1 | c.306dup p.A103Cfs*3 | Frame Shift Ins (INS) | VAF 25/68 reads (37%) | catalogued as rs752439249; called by mutect2, varscan2
- MAGEB6 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 75/388 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.541); catalogued as rs752693125, COSV100983703, COSV66871759; called by muse, mutect2, varscan2
- MAP3K4 | c.4096G>A p.G1366R | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100815616, COSV62329900; called by muse, mutect2, varscan2
- METTL15 | c.721C>G p.Q241E | Missense Mutation (SNP) | VAF 62/320 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0.02); catalogued as COSV100327862; called by muse, mutect2, varscan2
- MFF | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100449281; called by muse, mutect2, varscan2
- MYO3A | c.3305G>T p.R1102I | Missense Mutation (SNP) | VAF 73/288 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1490563938, COSV56350940; called by muse, mutect2, varscan2
- NFASC | c.1888C>T p.R630W (on ENST00000339876 / NM_001378329.1; = p.R626W on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs372883476; called by muse, mutect2, varscan2
- NLRC3 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 67/387 reads (17%) | SIFT tolerated (0.99); PolyPhen benign (0.006); catalogued as rs1452666120, COSV100072499; called by muse, mutect2, varscan2
- OR10J5 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as rs760004484, COSV100604845; called by muse, mutect2, varscan2
- OR4A16 | c.314T>G p.L105R | Missense Mutation (SNP) | VAF 24/402 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.434); catalogued as COSV59043856, COSV59044552; called by muse, mutect2
- OR4K15 | c.773C>T p.A258V (on ENST00000305051; = p.A234V on NM_001005486.1) | Missense Mutation (SNP) | VAF 99/300 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs750493574, COSV59300693; called by muse, mutect2, varscan2
- OR52E6 | c.501G>T p.R167S | Missense Mutation (SNP) | VAF 67/351 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1183253130, COSV61432564; called by muse, mutect2, varscan2
- OR6B3 | c.569C>T p.T190M | Missense Mutation (SNP) | VAF 151/488 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.065); catalogued as rs199762548; called by muse, mutect2, varscan2
- PAXBP1 | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1162230990; called by muse, mutect2, varscan2
- PCDHA7 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 286/1055 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs551745791, COSV65346407; called by muse, mutect2, varscan2
- PCDHB6 | c.1891C>T p.R631* | Nonsense Mutation (SNP) | VAF 244/850 reads (29%) | catalogued as COSV50704903; called by muse, mutect2, varscan2
- PCDHGB3 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 145/620 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54009214; called by muse, mutect2, varscan2
- PIAS3 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 65/242 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs201676296; called by muse, mutect2, varscan2
- PPIB | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 229/721 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.075); catalogued as rs759753798, COSV55519883; called by muse, mutect2, varscan2
- RAD54L2 | c.2698C>T p.R900W | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs768057918; called by muse, mutect2, varscan2
- RALGPS1 | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs768682056, COSV52219554; called by muse, mutect2, varscan2
- RDH8 | c.820C>T p.R274C (on ENST00000651512; = p.R254C on NM_015725.4) | Missense Mutation (SNP) | VAF 44/297 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1453109297; called by muse, mutect2, varscan2
- RGPD3 | c.4339C>T p.R1447C | Missense Mutation (SNP) | VAF 73/428 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as rs761052444, COSV100450914; called by muse, mutect2, varscan2
- RHBDL3 | c.532C>A p.L178I | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.338); catalogued as COSV52189609; called by muse, mutect2
- SAMD7 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 50/262 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs775356916, COSV100157069; called by muse, mutect2, varscan2
- SBK2 | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 76/132 reads (58%) | catalogued as COSV100705104; called by muse, mutect2, varscan2
- SHROOM1 | c.2504G>A p.R835Q (on ENST00000378679 / NM_001172700.2; = p.R830Q on NM_133456.2) | Missense Mutation (SNP) | VAF 64/236 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV60582419; called by muse, mutect2, varscan2
- SIDT1 | c.310C>A p.L104M | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.944); catalogued as COSV99333898; called by muse, mutect2
- SLC2A1 | c.19-2A>C p.X7_splice | Splice Site (SNP) | VAF 106/362 reads (29%) | catalogued as CS1414950; called by muse, mutect2, varscan2
- SPATA31E1 | c.3170C>T p.S1057L | Missense Mutation (SNP) | VAF 57/468 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.606); catalogued as rs145805743, COSV57795005; called by muse, mutect2, varscan2
- STK4 | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 154/454 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.354); catalogued as rs746946767, COSV65669423; called by muse, mutect2, varscan2
- STX11 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 196/620 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs779925697; called by muse, mutect2, varscan2
- TBX18 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 97/340 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as rs1302303681, COSV100858509; called by muse, mutect2, varscan2
- TEAD4 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1173967174; called by muse, mutect2, varscan2
- TMEM132D | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 37/194 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1209970085; called by muse, mutect2, varscan2
- TMEM132E | c.1169C>A p.S390Y (on ENST00000321639; = p.S480Y on NM_001304438.2) | Missense Mutation (SNP) | VAF 16/197 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV58695194, COSV58700681; called by muse, mutect2
- TRIM11 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778866651, COSV52860323; called by muse, mutect2, varscan2
- UNC80 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs746156861, COSV55888247; called by muse, mutect2, varscan2
- YPEL5 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as rs1036171918; called by muse, mutect2
- ZNF518B | c.2458G>A p.D820N | Missense Mutation (SNP) | VAF 45/380 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100456658; called by muse, mutect2, varscan2
- ACSL6 | c.1076G>T p.C359F (on ENST00000379240; = p.C384F on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- ACTRT1 | c.1075A>G p.T359A | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); called by muse, mutect2
- ADGRB3 | c.264T>A p.Y88* | Nonsense Mutation (SNP) | VAF 16/229 reads (7%) | called by muse, mutect2
- ADGRG7 | c.1403C>T p.T468I | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2
- AHNAK | c.16438C>T p.L5480F | Missense Mutation (SNP) | VAF 31/330 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); called by muse, mutect2
- AMER1 | c.1198G>T p.E400* | Nonsense Mutation (SNP) | VAF 126/378 reads (33%) | called by mutect2, varscan2
- ANK3 | c.5393G>C p.S1798T | Missense Mutation (SNP) | VAF 75/311 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ASB4 | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 91/375 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BPTF | c.4880T>G p.L1627R | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- CAPN12 | c.904G>C p.D302H | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- CCNDBP1 | c.153G>T p.M51I | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- CDH20 | c.177G>C p.R59S | Missense Mutation (SNP) | VAF 88/226 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by mutect2, varscan2
- CDX2 | c.634A>G p.T212A | Missense Mutation (SNP) | VAF 15/286 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2
- CEACAM16 | c.217G>A p.G73S | Missense Mutation (SNP) | VAF 82/171 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CHM | c.1084C>A p.L362I | Missense Mutation (SNP) | VAF 79/279 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CTSE | c.329C>G p.T110S | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CXorf21 | c.667A>G p.K223E | Missense Mutation (SNP) | VAF 85/328 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- DHX40 | c.2201-1G>A p.X734_splice | Splice Site (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- DMXL1 | c.4456G>A p.A1486T | Missense Mutation (SNP) | VAF 19/242 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- EXOC3L2 | c.1927C>T p.R643W | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- FAM155A | c.664T>A p.Y222N | Missense Mutation (SNP) | VAF 130/572 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- FAM185A | c.416A>T p.Q139L | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FAM81A | c.167A>G p.D56G | Missense Mutation (SNP) | VAF 114/547 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- FAM83B | c.2849C>A p.T950K | Missense Mutation (SNP) | VAF 41/338 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- FGD6 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FN1 | c.1797C>G p.C599W | Missense Mutation (SNP) | VAF 27/253 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GCGR | c.968_971del p.V323Afs*29 | Frame Shift Del (DEL) | VAF 81/261 reads (31%) | called by mutect2, pindel, varscan2
- GTF2B | c.187G>C p.D63H | Missense Mutation (SNP) | VAF 11/274 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- HERC2 | c.13061A>G p.H4354R | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- HIPK2 | c.97A>G p.I33V | Missense Mutation (SNP) | VAF 82/317 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IFNG | c.293A>G p.E98G | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- IL1RAPL1 | c.1683T>G p.F561L | Missense Mutation (SNP) | VAF 56/765 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0.005); called by muse, mutect2
- ITIH6 | c.3023T>A p.L1008Q | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.536); called by muse, mutect2
- IZUMO4 | c.13C>G p.L5V | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- KALRN | c.8011G>C p.G2671R (on ENST00000360013 / NM_001024660.4; = p.G974R on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- KCNA4 | c.1616T>G p.I539S | Missense Mutation (SNP) | VAF 70/290 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KCNH8 | c.2227G>A p.G743R | Missense Mutation (SNP) | VAF 24/245 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.463); called by muse, mutect2
- KIAA1210 | c.2853C>A p.F951L | Missense Mutation (SNP) | VAF 124/307 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- LAMA4 | c.2324A>G p.N775S (on ENST00000230538 / NM_001105206.3; = p.N768S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 120/423 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- LAS1L | c.1355G>A p.R452K | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- LCA5 | c.1352del p.M451Rfs*12 | Frame Shift Del (DEL) | VAF 80/240 reads (33%) | called by mutect2, pindel, varscan2
- LOXHD1 | c.3379G>C p.A1127P | Missense Mutation (SNP) | VAF 63/174 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- LRP1B | c.2341C>A p.L781I | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.83); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- MAP3K1 | c.4265G>C p.R1422T | Missense Mutation (SNP) | VAF 66/216 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MARCHF10 | c.732T>A p.S244R | Missense Mutation (SNP) | VAF 47/220 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- MCM5 | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYOD1 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NCOA2 | c.2376C>A p.S792R | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPHP3 | c.3944T>C p.L1315S | Missense Mutation (SNP) | VAF 25/337 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); called by muse, mutect2
- NPHP3 | c.3943T>A p.L1315I | Missense Mutation (SNP) | VAF 25/352 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.01); called by muse, mutect2
- NUDCD1 | c.460-2A>T p.X154_splice | Splice Site (SNP) | VAF 17/61 reads (28%) | called by muse, mutect2, varscan2
- OR10G8 | c.649T>C p.Y217H | Missense Mutation (SNP) | VAF 80/392 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OTOG | c.2565dup p.G856Rfs*4 | Frame Shift Ins (INS) | VAF 87/365 reads (24%) | called by mutect2, pindel, varscan2
- OXCT1 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 90/321 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDHB16 | c.1060A>T p.S354C | Missense Mutation (SNP) | VAF 98/392 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- PCDHGB1 | c.61T>C p.S21P | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCDHGB6 | c.536C>A p.S179* | Nonsense Mutation (SNP) | VAF 67/290 reads (23%) | called by muse, mutect2, varscan2
- PNPT1 | c.1841T>G p.L614* | Nonsense Mutation (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- PRG4 | c.3710G>A p.G1237E | Missense Mutation (SNP) | VAF 23/292 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2
- PRPF4B | c.2725C>T p.P909S | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRR9 | c.185A>C p.Q62P | Missense Mutation (SNP) | VAF 82/284 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.067); called by mutect2, varscan2
- PTK7 | c.3076C>A p.L1026I | Missense Mutation (SNP) | VAF 76/233 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- RADX | c.1652C>G p.A551G | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- RASGRF1 | c.3548A>T p.D1183V | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- RGS1 | c.323G>A p.S108N | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RGS7 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 75/288 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ROBO2 | c.2610G>A p.W870* | Nonsense Mutation (SNP) | VAF 43/452 reads (10%) | called by muse, mutect2, varscan2
- SHANK1 | c.5395G>C p.A1799P | Missense Mutation (SNP) | VAF 200/371 reads (54%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- SIGLEC10 | c.583T>A p.S195T | Missense Mutation (SNP) | VAF 175/344 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.02); called by mutect2, varscan2
- SLC26A1 | c.1480_1482del p.V494del | In Frame Del (DEL) | VAF 72/297 reads (24%) | called by mutect2, pindel, varscan2
- SLC6A14 | c.1738A>T p.M580L | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0); called by mutect2, varscan2
- SNRPC | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SOX5 | c.608T>G p.M203R | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- SOX9 | c.1037dup p.Q347Afs*231 | Frame Shift Ins (INS) | VAF 12/42 reads (29%) | called by mutect2, pindel
- SYCP1 | c.1527G>A p.E509= | Splice Region (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- SYNE1 | c.3742T>G p.L1248V (on ENST00000367255 / NM_182961.4; = p.L1255V on NM_033071.3) | Missense Mutation (SNP) | VAF 29/304 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.194); called by muse, mutect2
- TLR7 | c.2351G>A p.R784Q | Missense Mutation (SNP) | VAF 121/524 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- TRAPPC3L | c.490A>C p.I164L | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TRIM64C | c.1319C>T p.P440L | Missense Mutation (SNP) | VAF 107/326 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- TRIM71 | c.706C>A p.H236N | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TSEN15 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TTN | c.88837A>C p.M29613L (on ENST00000591111; = p.M22189L on NM_003319.4) | Missense Mutation (SNP) | VAF 44/592 reads (7%) | PolyPhen benign (0.013); called by muse, mutect2
- TTN | c.68702C>A p.P22901Q (on ENST00000591111; = p.P15477Q on NM_003319.4) | Missense Mutation (SNP) | VAF 22/378 reads (6%) | PolyPhen possibly damaging (0.701); called by muse, mutect2
- TTN | c.61047C>A p.N20349K (on ENST00000591111; = p.N12925K on NM_003319.4) | Missense Mutation (SNP) | VAF 14/216 reads (6%) | PolyPhen probably damaging (0.943); called by muse, mutect2
- TYW1B | c.1867G>A p.G623R | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- USP40 | c.3035A>G p.E1012G | Missense Mutation (SNP) | VAF 44/203 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- VPS13A | c.1168G>C p.E390Q | Missense Mutation (SNP) | VAF 38/223 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR27 | c.620C>A p.A207E | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- ZC3H12B | c.1113C>A p.H371Q | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); called by muse, mutect2
- ZC3H13 | c.1942C>G p.Q648E | Missense Mutation (SNP) | VAF 8/214 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2
- ZNF180 | c.1541C>T p.T514I | Missense Mutation (SNP) | VAF 136/291 reads (47%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ZNF267 | c.79A>G p.N27D | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- ZNF277 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF536 | c.1277T>G p.L426R | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADAMTSL2 | c.1626C>T p.A542= | Silent (SNP) | VAF 101/357 reads (28%) | catalogued as rs985213789; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRV1 | c.9696T>C p.D3232= | Silent (SNP) | VAF 11/187 reads (6%) | called by muse, mutect2
- ANK2 | c.2364C>T p.N788= | Silent (SNP) | VAF 84/351 reads (24%) | catalogued as rs769405364, COSV52152112; called by muse, mutect2, varscan2
- ANXA7 | c.930C>T p.D310= (on ENST00000372919 / NM_001320880.2; = p.D288= on NM_001156.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 87/223 reads (39%) | catalogued as COSV65824763; called by muse, mutect2, varscan2
- CACNA1B | c.1938C>T p.F646= | Silent (SNP) | VAF 56/285 reads (20%) | catalogued as rs1340487260, COSV99500379; called by muse, mutect2, varscan2
- CARS2 | c.450C>T p.D150= | Silent (SNP) | VAF 12/243 reads (5%) | catalogued as COSV57283739; called by muse, mutect2
- CLDN19 | c.105C>T p.Y35= | Silent (SNP) | VAF 221/696 reads (32%) | catalogued as rs760544476, COSV56419471; called by muse, mutect2, varscan2
- CLEC18C | c.432C>T p.N144= | Silent (SNP) | VAF 52/645 reads (8%) | catalogued as rs1197360996, COSV58499693; called by muse, mutect2
- CPAMD8 | c.3822C>T p.F1274= (on ENST00000651564; = p.F1227= on NM_015692.5) | Silent (SNP) | VAF 11/138 reads (8%) | catalogued as rs750599747, COSV71596370, COSV71596814, COSV71597034; called by muse, mutect2
- CSNK2A2 | c.1026T>A p.L342= | Silent (SNP) | VAF 35/135 reads (26%) | called by muse, mutect2, varscan2
- DCBLD1 | c.228G>A p.K76= | Silent (SNP) | VAF 76/282 reads (27%) | called by muse, mutect2, varscan2
- DPF3 | c.756G>A p.P252= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs374644462; called by muse, mutect2, varscan2
- EPHA10 | c.63C>T p.L21= | Silent (SNP) | VAF 44/180 reads (24%) | catalogued as rs753433742, COSV100140132; called by muse, mutect2, varscan2
- ERN2 | c.1593C>T p.G531= | Silent (SNP) | VAF 26/231 reads (11%) | catalogued as rs375355404, COSV99890746; called by muse, mutect2, varscan2
- EXPH5 | c.4158C>G p.G1386= | Silent (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2
- FBLL1 | c.342G>A p.A114= | Silent (SNP) | VAF 44/135 reads (33%) | called by muse, mutect2, varscan2
- FLT4 | c.909C>T p.H303= | Silent (SNP) | VAF 135/639 reads (21%) | catalogued as rs540014376, COSV56118699; called by muse, mutect2, varscan2
- FZR1 | c.1068G>A p.A356= | Silent (SNP) | VAF 81/193 reads (42%) | catalogued as rs778024704, COSV58053707; called by muse, mutect2, varscan2
- GALNT9 | c.1299G>A p.R433= (on ENST00000328957 / NM_001122636.2; = p.R67= on NM_021808.3) | Silent (SNP) | VAF 41/206 reads (20%) | called by muse, mutect2, varscan2
- GLIS1 | c.1329T>C p.P443= | Silent (SNP) | VAF 21/121 reads (17%) | called by muse, mutect2, varscan2
- GOLPH3 | c.855C>G p.T285= | Silent (SNP) | VAF 15/172 reads (9%) | called by muse, mutect2
- GRIPAP1 | c.1008T>C p.N336= | Silent (SNP) | VAF 38/156 reads (24%) | called by muse, mutect2, varscan2
- GSG1 | c.234G>A p.L78= (on ENST00000651961 / NM_001080555.4; = p.L65= on NM_031289.5) | Silent (SNP) | VAF 58/624 reads (9%) | called by muse, mutect2
- HABP4 | c.1233G>A p.A411= | Silent (SNP) | VAF 27/165 reads (16%) | catalogued as rs376431061; called by muse, mutect2, varscan2
- HMCN2 | c.14604C>T p.R4868= | Silent (SNP) | VAF 22/118 reads (19%) | catalogued as rs1049681572, COSV56739941; called by muse, mutect2, varscan2
- HYDIN | c.702C>T p.H234= | Silent (SNP) | VAF 86/326 reads (26%) | catalogued as rs771242721; called by muse, mutect2, varscan2
- IL32 | c.552C>A p.V184= (on ENST00000396890 / NM_001308078.4; = p.V138= on NM_004221.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 82/359 reads (23%) | called by mutect2, varscan2
- ITIH1 | c.849C>T p.P283= | Silent (SNP) | VAF 21/281 reads (7%) | called by muse, mutect2
- KDM6A | c.1953G>A p.S651= | Silent (SNP) | VAF 71/274 reads (26%) | catalogued as rs541289730, COSV100938021; called by muse, mutect2, varscan2
- LRRC24 | c.1251G>A p.T417= | Silent (SNP) | VAF 52/191 reads (27%) | called by muse, mutect2, varscan2
- LRRIQ1 | c.4062G>A p.Q1354= | Silent (SNP) | VAF 32/186 reads (17%) | called by muse, mutect2, varscan2
- MAP3K11 | c.1521A>T p.S507= | Silent (SNP) | VAF 27/111 reads (24%) | called by muse, mutect2, varscan2
- MUC1 | c.3141C>G p.V1047= (on ENST00000611571 / NM_001371720.1; = p.V58= on NM_002456.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 146/443 reads (33%) | catalogued as COSV58111966; called by muse, mutect2, varscan2
- MYO9B | c.1581C>T p.F527= | Silent (SNP) | VAF 47/130 reads (36%) | catalogued as rs1001545963, COSV68281121; called by muse, mutect2, varscan2
- N4BP2L1 | c.363C>G p.L121= | Silent (SNP) | VAF 38/136 reads (28%) | called by muse, mutect2, varscan2
- NAALADL2 | c.2346A>T p.A782= | Silent (SNP) | VAF 7/118 reads (6%) | called by muse, mutect2
- OR51M1 | c.678C>T p.I226= | Silent (SNP) | VAF 109/391 reads (28%) | catalogued as rs768874760; called by muse, mutect2, varscan2
- PAK5 | c.531C>T p.H177= | Silent (SNP) | VAF 175/673 reads (26%) | catalogued as COSV62039038; called by muse, mutect2, varscan2
- PCDHA10 | c.378C>T p.N126= | Silent (SNP) | VAF 105/429 reads (24%) | called by muse, mutect2, varscan2
- PCDHA6 | c.1506C>T p.R502= | Silent (SNP) | VAF 70/1131 reads (6%) | catalogued as COSV65348165; called by muse, mutect2
- PCSK6 | c.1908G>A p.P636= | Silent (SNP) | VAF 61/197 reads (31%) | catalogued as rs199785232; called by muse, mutect2, varscan2
- PCYT1B | c.417T>C p.C139= | Silent (SNP) | VAF 12/248 reads (5%) | called by muse, mutect2
- PFKFB4 | c.1209C>T p.L403= | Silent (SNP) | VAF 64/212 reads (30%) | catalogued as rs753061768, COSV51680200; called by muse, mutect2, varscan2
- PGRMC1 | c.261G>A p.P87= | Silent (SNP) | VAF 50/230 reads (22%) | called by muse, mutect2, varscan2
- PLK4 | c.2088A>G p.V696= | Silent (SNP) | VAF 14/132 reads (11%) | called by muse, mutect2
- PNPLA4 | c.231T>G p.S77= | Silent (SNP) | VAF 13/261 reads (5%) | catalogued as rs1263212934; called by muse, mutect2
- POLQ | c.1548C>T p.R516= | Silent (SNP) | VAF 27/94 reads (29%) | called by muse, mutect2, varscan2
- PRR14L | c.3480A>T p.A1160= | Silent (SNP) | VAF 26/303 reads (9%) | called by muse, mutect2
- PSD2 | c.1119G>A p.P373= | Silent (SNP) | VAF 50/164 reads (30%) | catalogued as rs200076969, COSV51199985; called by muse, mutect2, varscan2
- PTCHD1 | c.906C>T p.L302= | Silent (SNP) | VAF 200/515 reads (39%) | catalogued as rs749397302, COSV65059051; called by muse, mutect2, varscan2
- RFX6 | c.612C>T p.Y204= | Silent (SNP) | VAF 51/309 reads (17%) | called by muse, mutect2, varscan2
- RGPD8 | c.3465G>T p.L1155= | Silent (SNP) | VAF 120/1050 reads (11%) | called by mutect2, varscan2
- RPL23A | c.432C>T p.Y144= | Silent (SNP) | VAF 111/445 reads (25%) | catalogued as rs147131534; called by muse, mutect2, varscan2
- RYR3 | c.11379T>C p.I3793= (on ENST00000389232; = p.I3794= on NM_001036.6) | Silent (SNP) | VAF 46/192 reads (24%) | called by muse, mutect2, varscan2
- SCG2 | c.345C>T p.L115= | Silent (SNP) | VAF 146/360 reads (41%) | catalogued as rs372704649; called by muse, mutect2, varscan2
- SCN5A | c.537A>T p.R179= | Silent (SNP) | VAF 78/357 reads (22%) | called by muse, mutect2, varscan2
- SEC16B | c.2613C>T p.S871= | Silent (SNP) | VAF 64/210 reads (30%) | catalogued as rs373528898; called by muse, mutect2
- SHANK1 | c.5394G>A p.L1798= | Silent (SNP) | VAF 190/382 reads (50%) | called by muse, varscan2
- SLC22A25 | c.27A>G p.Q9= | Silent (SNP) | VAF 15/247 reads (6%) | catalogued as COSV60599307; called by muse, mutect2
- STC2 | c.78C>T p.D26= | Silent (SNP) | VAF 28/104 reads (27%) | catalogued as rs1486449854, COSV54178418; called by muse, mutect2, varscan2
- TAS2R31 | c.204A>C p.S68= | Silent (SNP) | VAF 64/260 reads (25%) | catalogued as rs763447755; called by muse, mutect2, varscan2
- TDRD9 | c.3558C>T p.D1186= | Silent (SNP) | VAF 59/157 reads (38%) | catalogued as rs762378412; called by muse, mutect2, varscan2
- TMEM247 | c.252C>T p.G84= | Silent (SNP) | VAF 80/317 reads (25%) | catalogued as rs368909438, COSV101417741; called by muse, mutect2, varscan2
- TSC22D3 | c.378C>T p.P126= | Silent (SNP) | VAF 179/395 reads (45%) | catalogued as rs375573985; called by muse, mutect2, varscan2
- USP18 | c.339C>T p.S113= | Silent (SNP) | VAF 29/133 reads (22%) | called by muse, mutect2, varscan2
- VCAN | c.6711G>A p.P2237= | Silent (SNP) | VAF 82/375 reads (22%) | catalogued as rs747734140, COSV54108886; called by muse, mutect2, varscan2
- VIT | c.984C>G p.A328= (on ENST00000389975 / NM_001177969.1; = p.A343= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/138 reads (33%) | catalogued as COSV101007423; called by muse, mutect2, varscan2
- VWC2 | c.387C>T p.D129= | Silent (SNP) | VAF 57/178 reads (32%) | called by muse, mutect2, varscan2
- ZFYVE28 | c.1530C>A p.G510= | Silent (SNP) | VAF 66/302 reads (22%) | called by muse, mutect2, varscan2
- ZNF318 | c.3390G>A p.L1130= | Silent (SNP) | VAF 39/174 reads (22%) | catalogued as rs766425260; called by muse, mutect2, varscan2
- AC244517.10 | c.36-10113A>C | Intron (SNP) | VAF 84/343 reads (24%) | catalogued as rs1265269745; called by muse, mutect2, varscan2
- ACSL6 | c.841+14C>T | Intron (SNP) | VAF 84/291 reads (29%) | catalogued as rs1321528353; called by muse, mutect2, varscan2
- AGTR1 | c.*101G>T | 3'UTR (SNP) | VAF 57/267 reads (21%) | catalogued as rs1451185420; called by muse, mutect2, varscan2
- ARHGEF4 | c.428-16247A>G | Intron (SNP) | VAF 105/363 reads (29%) | called by muse, mutect2, varscan2
- ASH1L | c.5828+4655C>T | Intron (SNP) | VAF 42/580 reads (7%) | catalogued as COSV64209930; called by muse, mutect2
- ATP6V1H | c.579+4306C>T | Intron (SNP) | VAF 11/196 reads (6%) | called by muse, mutect2
- C2orf49 | c.-5C>T | 5'UTR (SNP) | VAF 20/291 reads (7%) | called by muse, mutect2
- CACNG4 | c.*863G>A | 3'UTR (SNP) | VAF 102/320 reads (32%) | catalogued as rs938863226; called by muse, mutect2, varscan2
- CAPN8 | c.307+11514dup | Intron (INS) | VAF 16/91 reads (18%) | called by mutect2, pindel, varscan2
- CHTF18 | c.287-11G>C | Intron (SNP) | VAF 73/213 reads (34%) | called by muse, mutect2, varscan2
- CLC | c.-40C>G | 5'UTR (SNP) | VAF 38/94 reads (40%) | called by muse, mutect2, varscan2
- CLN5 | c.174-34G>C | Intron (SNP) | VAF 28/235 reads (12%) | called by muse, mutect2, varscan2
- CYP2B7P | n.247G>A | RNA (SNP) | VAF 44/391 reads (11%) | catalogued as rs762034653; called by muse, mutect2, varscan2
- ELOVL5 | c.58+1248A>C | Intron (SNP) | VAF 78/266 reads (29%) | called by muse, mutect2, varscan2
- FMR1 | c.*2277A>T | 3'UTR (SNP) | VAF 11/101 reads (11%) | called by muse, mutect2
- FMR1 | c.*2279A>T | 3'UTR (SNP) | VAF 11/99 reads (11%) | called by muse, mutect2
- G6PC3 | c.*47C>G | 3'UTR (SNP) | VAF 191/677 reads (28%) | called by muse, mutect2, varscan2
- GASK1A | c.1413+23C>T | Intron (SNP) | VAF 46/542 reads (8%) | called by muse, mutect2
- GUSBP3 | chr5:69635277 C>T | 3'Flank (SNP) | VAF 40/290 reads (14%) | called by muse, mutect2
- HBS1L | c.-3dup | 5'UTR (INS) | VAF 12/40 reads (30%) | catalogued as rs956648284; called by mutect2, varscan2
- IGFBP3 | chr7:45921675 G>A | 5'Flank (SNP) | VAF 52/148 reads (35%) | called by muse, mutect2, varscan2
- KIF26B | c.999+3280C>T | Intron (SNP) | VAF 49/151 reads (32%) | catalogued as rs775285883; called by muse, mutect2, varscan2
- LENG8 | c.*2408G>C | 3'UTR (SNP) | VAF 65/115 reads (57%) | catalogued as COSV56618553; called by mutect2, varscan2
- LINC01101 | n.182G>C | RNA (SNP) | VAF 23/710 reads (3%) | called by muse, mutect2
- LPIN1 | c.1250+19C>T | Intron (SNP) | VAF 132/457 reads (29%) | catalogued as rs767874622; called by muse, mutect2, varscan2
- LRRC6 | c.1226+5189G>T | Intron (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- MGAT4FP | n.525C>T | RNA (SNP) | VAF 40/158 reads (25%) | called by muse, mutect2, varscan2
- MOB3A | c.*9C>T | 3'UTR (SNP) | VAF 20/164 reads (12%) | catalogued as rs771868773; called by muse, mutect2, varscan2
- MRPS17P9 | n.131A>G | RNA (SNP) | VAF 113/352 reads (32%) | called by muse, mutect2, varscan2
- NDUFV3 | c.170-4856G>A | Intron (SNP) | VAF 30/328 reads (9%) | catalogued as rs377638949; called by muse, mutect2
- NRXN1 | c.3365-109891G>A | Intron (SNP) | VAF 23/65 reads (35%) | catalogued as rs758537751; called by muse, mutect2, varscan2
- OR2U1P | n.790G>C | RNA (SNP) | VAF 76/217 reads (35%) | called by muse, mutect2, varscan2
- PCDHA9 | c.2394+25A>C | Intron (SNP) | VAF 40/126 reads (32%) | called by muse, mutect2, varscan2
- POLR1D | c.27-12dup | Intron (INS) | VAF 140/369 reads (38%) | catalogued as rs1411951922; called by mutect2, pindel, varscan2
- RNA5-8SP2 | chr16:34158789 C>T | 5'Flank (SNP) | VAF 44/160 reads (28%) | catalogued as rs796734168; called by muse, mutect2, varscan2
- SERPINA13P | n.701A>T | RNA (SNP) | VAF 68/176 reads (39%) | called by muse, varscan2
- SHMT1 | c.520-51C>T | Intron (SNP) | VAF 42/458 reads (9%) | called by muse, mutect2
- SPATA7 | c.239-1484C>G | Intron (SNP) | VAF 13/59 reads (22%) | called by muse, mutect2, varscan2
- SYT17 | c.16-133A>T | Intron (SNP) | VAF 33/126 reads (26%) | called by mutect2, varscan2
- SYTL5 | c.1155+652G>C | Intron (SNP) | VAF 68/163 reads (42%) | called by muse, mutect2, varscan2
- TAFA5 | c.112+49692G>C | Intron (SNP) | VAF 46/172 reads (27%) | called by muse, mutect2, varscan2
- TEX30 | c.16-22C>A | Intron (SNP) | VAF 40/174 reads (23%) | catalogued as rs991445359; called by muse, mutect2, varscan2
- TTN | c.10360+2974T>G | Intron (SNP) | VAF 46/622 reads (7%) | called by muse, mutect2
- XIST | n.10457A>C | RNA (SNP) | VAF 35/454 reads (8%) | called by muse, mutect2
- Y_RNA | chr7:23490911 A>T | 3'Flank (SNP) | VAF 172/575 reads (30%) | called by muse, mutect2, varscan2
